Somatic mutation profile of tumor specimen 0DH5VP from CCDI case PBBTFZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 10.5 years (3,833 days).
Specimen 0DH5VP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d65cb575-ae98-46f8-8db6-26b789c654ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH5U7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87c821ef-d787-4d65-b05b-3e93da7ed000

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, 3'UTR 3, Frame Shift Del 2, Intron 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABTB1 | c.1063G>A p.V355I (on ENST00000232744 / NM_172027.3; = p.V213I on NM_032548.3) | Missense Mutation (SNP) | VAF 59/1253 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs554345628, COSV51741868; called by muse, mutect2
- DEPTOR | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 570/1865 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as rs375154981; called by muse, mutect2, varscan2
- GRIP2 | c.2668G>A p.E890K (on ENST00000619221; = p.E793K on NM_001080423.4) | Missense Mutation (SNP) | VAF 258/724 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); catalogued as rs759811179, COSV56120637; called by muse, varscan2
- KCNB1 | c.2093G>T p.R698L | Missense Mutation (SNP) | VAF 144/808 reads (18%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.06); catalogued as COSV100870372, COSV65570211; called by muse, varscan2
- PKLR | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 225/1423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748376799, CM061889; called by muse, mutect2, varscan2
- SP140 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 152/1220 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs201286206; called by muse, mutect2, varscan2
- ACTN3 | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 144/695 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- CRYBB1 | c.559A>G p.K187E | Missense Mutation (SNP) | VAF 40/1462 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2
- GALNT9 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 145/755 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- GDPD4 | c.1281del p.V428Sfs*18 | Frame Shift Del (DEL) | VAF 428/943 reads (45%) | called by mutect2, varscan2
- NOC2L | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 222/967 reads (23%) | called by muse, mutect2, varscan2
- OR10AG1 | c.810_814del p.I271Dfs*26 | Frame Shift Del (DEL) | VAF 144/884 reads (16%) | called by mutect2, varscan2
- PTPRC | c.2148C>A p.F716L | Missense Mutation (SNP) | VAF 26/881 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- RNGTT | c.920C>A p.T307K | Missense Mutation (SNP) | VAF 70/891 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- SH3RF2 | c.1060-1G>T p.X354_splice | Splice Site (SNP) | VAF 64/472 reads (14%) | called by muse, mutect2, varscan2
- TWSG1 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 45/1016 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.27); called by muse, mutect2
- MYO18B | c.5892C>T p.I1964= | Silent (SNP) | VAF 108/2052 reads (5%) | catalogued as rs761196562, COSV59150472; called by muse, mutect2
- NR1H4 | c.906G>A p.T302= (on ENST00000551379 / NM_001206993.2; = p.T288= on NM_005123.4) | Silent (SNP) | VAF 37/1316 reads (3%) | catalogued as rs1193074710; called by muse, mutect2
- RMDN1 | c.474A>G p.E158= | Silent (SNP) | VAF 91/790 reads (12%) | called by muse, mutect2, varscan2
- SF3B2 | c.2481G>A p.A827= | Silent (SNP) | VAF 197/965 reads (20%) | catalogued as rs371699615; called by muse, mutect2, varscan2
- SRF | c.1194C>T p.S398= | Silent (SNP) | VAF 328/816 reads (40%) | catalogued as rs766337868, COSV52735469; called by muse, varscan2
- AC144573.1 | c.*431A>G | 3'UTR (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- ANTXR2 | c.*6A>G | 3'UTR (SNP) | VAF 38/1122 reads (3%) | called by muse, mutect2
- BACE1 | c.943-55G>T | Intron (SNP) | VAF 13/266 reads (5%) | called by muse, mutect2
- ITPKA | c.*18C>T | 3'UTR (SNP) | VAF 56/308 reads (18%) | catalogued as rs374862102, COSV53029392, COSV99540497; called by muse, mutect2, varscan2
- OOSP2 | c.243+41G>T | Intron (SNP) | VAF 190/351 reads (54%) | called by muse, mutect2, varscan2
